Somatic mutation profile of tumor specimen TCGA-LN-A8HZ-01A (aliquot TCGA-LN-A8HZ-01A-11D-A36J-09) from TCGA case TCGA-LN-A8HZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 56.2 years (20,510 days).
Specimen TCGA-LN-A8HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b99ec385-3482-440f-ac14-24fd87107873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A8HZ-10A (Blood Derived Normal), aliquot TCGA-LN-A8HZ-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee3213d-da1c-4426-97f5-1da77181452c

The open-access MAF lists 93 somatic variants for this specimen: 79 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 12, Frame Shift Ins 5, Nonsense Mutation 4, Frame Shift Del 4, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 34/65 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- TP53 | c.994-2A>C p.X332_splice | Splice Site (SNP) | VAF 8/11 reads (73%) | hotspot (GDC flag); catalogued as CS159286, COSV52692098, COSV52692518, COSV53122371; called by muse, mutect2, varscan2
- ACO1 | c.1856_1857del p.V619Efs*2 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as rs982368311; called by pindel, varscan2
- ANKH | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as COSV52484799; called by muse, mutect2, varscan2
- ATP6V1H | c.339C>G p.D113E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.105); catalogued as rs1166635957; called by muse, mutect2, varscan2
- BPIFA2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs758880003, COSV53611272; called by muse, mutect2, varscan2
- CD1A | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV56860252; called by muse, mutect2, varscan2
- CHD1 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.535); catalogued as COSV99399129; called by muse, mutect2, varscan2
- CHD8 | c.5065A>T p.K1689* (on ENST00000646647 / NM_001170629.2; = p.K1410* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as rs1555313726; called by muse, mutect2
- COL27A1 | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs141872540; called by muse, mutect2, varscan2
- CPT1B | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs767195024; called by muse, mutect2, varscan2
- CYP2D6 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1445160365; called by muse, mutect2, varscan2
- DHX15 | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61026720; called by muse, mutect2
- ELMO2 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs113022678; called by muse, mutect2, varscan2
- FBXW5 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs371147879, COSV56403693, COSV99812276; called by muse, mutect2, varscan2
- KARS1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); catalogued as COSV56692739; called by muse, mutect2
- LDB3 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs748672176, COSV53950974; called by muse, mutect2, varscan2
- NRDE2 | c.1564T>C p.F522L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV62962644; called by muse, mutect2
- PCDHA9 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs562563367, COSV100970016; called by muse, mutect2
- PCDHB4 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as rs1302319280, COSV99521822; called by muse, varscan2
- PREPL | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs769885236; called by muse, mutect2, varscan2
- RABGEF1 | c.141C>G p.F47L (on ENST00000439720 / NM_001287061.2; = p.F34L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99535230; called by muse, mutect2
- SLC24A1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs746325831, COSV56051234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.20380G>T p.V6794L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs202235545, COSV59971693; called by muse, mutect2, varscan2
- TNFSF9 | c.543G>C p.L181F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV55537836; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1583A>T p.Y528F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61457961; called by muse, mutect2, varscan2
- UBR2 | c.4790C>A p.S1597Y | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV65749050; called by muse, mutect2
- UPP1 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773220996, COSV100080809; called by muse, mutect2, varscan2
- XCR1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1048870025, COSV58569095; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- ANKS3 | c.1364T>A p.I455N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATR | c.3341dup p.S1115Ifs*3 | Frame Shift Ins (INS) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- C7 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CAMKMT | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CDC14B | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CDH11 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CELF4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CHUK | c.1936del p.R646Gfs*22 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- CNR1 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DAP3 | c.1165_1166dup p.L390Rfs*32 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- DLX4 | c.338C>A p.P113H (on ENST00000240306 / NM_138281.3; = p.P41H on NM_001934.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- DNAJC17 | c.220A>C p.K74Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- EIF2AK1 | c.1716_1717dup p.S573Yfs*24 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- FAM135A | c.417G>C p.K139N (on ENST00000370479 / NM_001351599.1; = p.K96N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GNPAT | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPR182 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCAR3 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- HEPH | c.2123G>T p.G708V (on ENST00000343002; = p.G441V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HERC1 | c.7754G>A p.G2585E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- HM13 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMCN1 | c.14056G>T p.E4686* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- HTR3C | c.664A>C p.K222Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- HTRA1 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- KLRD1 | c.260A>T p.H87L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KMT2D | c.9109del p.H3037Tfs*34 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- KRTAP5-9 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- LAMTOR1 | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP3K12 | c.1071C>G p.F357L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL22 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MUC16 | c.19893C>A p.D6631E | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NCOR1 | c.6626A>T p.K2209M | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUP214 | c.1596del p.T533Pfs*38 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- OR52N1 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PARD3 | c.3265A>T p.T1089S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PHOX2B | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2
- POT1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPWD1 | c.1435A>G p.M479V | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTX4 | c.1169G>A p.R390K (on ENST00000447419 / NM_001328608.2; = p.R385K on NM_001013658.1) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SHTN1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.066); called by muse, mutect2
- SIGLEC10 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A3 | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- SMC2 | c.2391dup p.L798Tfs*12 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.3960_3967dup p.L1323Hfs*81 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, varscan2
- TFAP2D | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD7B | c.668C>A p.S223* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- TPR | c.2049A>T p.K683N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- USP34 | c.5434G>A p.E1812K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VNN1 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.4729C>T p.L1577F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ADAM30 | c.400C>A p.R134= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1174254376; called by muse, mutect2, varscan2
- CTBP1 | c.1308C>T p.A436= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- IGF2 | c.27C>A p.I9= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- IGSF21 | c.840C>T p.S280= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs762318783, COSV52143193, COSV52145363; called by muse, mutect2, varscan2
- INHBB | c.660C>T p.D220= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- SLC18A2 | c.528T>C p.F176= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SLC4A2 | c.2454C>T p.F818= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs372791857; called by mutect2, varscan2
- SLK | c.1305C>T p.D435= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- SMARCA4 | c.1230G>A p.L410= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- SMURF2 | c.1959C>T p.V653= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV52312475; called by muse, mutect2, varscan2
- USH2A | c.8295C>T p.H2765= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- XPO5 | c.1038A>G p.P346= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs1435125030, COSV54831872; called by muse, mutect2, varscan2
- LINC01559 | n.395G>T | RNA (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- PGAM5 | c.719+656T>C | Intron (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
